Gene-level copy-number profile of tumor specimen TCGA-13-0910-01A from TCGA case TCGA-13-0910, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 58.8 years (21,473 days).
Specimen TCGA-13-0910-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.72c6537f-1ae7-47d8-8b7c-43d393dffd3c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0910-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/122efe99-abd4-4e68-80bc-dd63d82bbf7e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 20,896; copy number 2: 32,786; copy number 3: 5,830; copy number 4: 239; copy number 5: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-0910-01A-01D-0399-01): tumor purity 0.77, ploidy 1.77, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:3,500,976–4,116,442, 15 genes (within-gene range 0–1): CLUAP1, AC004494.2, NLRC3, AC004494.1, AC006111.1, SLX4, DNASE1, AC006111.2, TRAP1, AC006111.3, CREBBP, AC007151.1, LINC02861, ADCY9, AC005736.1.
- chr16:68,573,782–68,835,541, 12 genes (within-gene range 0–1): AC126773.3, AC126773.6, AC126773.1, AC126773.2, CDH3, AC126773.4, AC126773.5, HSPE1P5, CDH1, RNA5SP429, AC099314.1, FTLP14.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 37 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:174,057,641–174,378,005, 3 genes, copy number 5: RN7SKP234, ANAPC15P2, AC069218.1.
- chr3:186,476,727–187,078,553, 34 genes, copy number 5: LINC02051, CRYGS, TBCCD1, DNAJB11, AC068631.1, AC068631.2, AC068631.3, AHSG, Metazoa_SRP, FETUB, HRG, AC109780.1, AC109780.2, KNG1, PSMD10P2, RNU6-1105P, GPS2P2, AC112907.3, EIF4A2, SNORD2, SNORA63B, MIR1248, SNORA81, SNORA63, SNORA4, RFC4, AC112907.1, LINC02043, AC112907.2, ADIPOQ, ADIPOQ-AS1, RPS20P14, AC007690.1, ST6GAL1.

Autosomal genes at a single copy (total copy number 1): 18,475. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
